Somatic mutation profile of tumor specimen TCGA-43-2576-01A (aliquot TCGA-43-2576-01A-01D-1522-08) from TCGA case TCGA-43-2576, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-43-2576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02e31168-f644-4e58-b7d3-bd22634523d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-2576-11A (Solid Tissue Normal), aliquot TCGA-43-2576-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ed29d01-ab92-46bb-adde-5f3596f68bf4

The open-access MAF lists 548 somatic variants for this specimen: 431 protein-altering or splice-affecting, 105 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 105, Nonsense Mutation 42, Splice Site 12, Frame Shift Del 9, Splice Region 7, RNA 4, 5'Flank 3, Intron 3, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ABCA13 | c.11147C>A p.T3716K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101446788; called by muse, mutect2, varscan2
- ABCA9 | c.1792-1G>T p.X598_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100382645; called by muse, mutect2, varscan2
- ABCD2 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100429170; called by muse, mutect2, varscan2
- ABI3BP | c.2649G>A p.M883I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99425496; called by muse, mutect2, varscan2
- AC105001.2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100134684; called by muse, mutect2
- ACAP2 | c.1323C>T p.H441= | Splice Region (SNP) | VAF 51/253 reads (20%) | catalogued as COSV100461494; called by muse, mutect2, varscan2
- ACTL9 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.274); catalogued as COSV100185125; called by muse, mutect2, varscan2
- ACTR5 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1202164711, COSV99709900; called by muse, mutect2, varscan2
- ACTRT1 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100947507; called by muse, mutect2, varscan2
- ADCY8 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53927119, COSV99650847; called by muse, mutect2, varscan2
- ADGRF5 | c.2652C>G p.D884E | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV51938893, COSV99344953; called by muse, mutect2, varscan2
- ADGRG4 | c.2155G>C p.A719P | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99794434; called by muse, mutect2, varscan2
- ADGRG4 | c.2790G>T p.M930I | Missense Mutation (SNP) | VAF 89/378 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99794435; called by muse, mutect2, varscan2
- ADPRH | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100813269; called by muse, mutect2, varscan2
- AGA | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CS991287, COSV99219366; called by muse, mutect2, varscan2
- AGO3 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV99868024; called by muse, mutect2, varscan2
- AGPAT1 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100421543; called by muse, mutect2, varscan2
- AHNAK | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99945704; called by muse, mutect2, varscan2
- AKAP6 | c.253C>G p.R85G | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99798512; called by muse, mutect2, varscan2
- ALX4 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100240908; called by muse, mutect2, varscan2
- AMBN | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as COSV100534268; called by muse, mutect2, varscan2
- AMDHD2 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV53552120, COSV99565622; called by muse, mutect2, varscan2
- AMER1 | c.2592G>T p.W864C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57659346; called by muse, mutect2, varscan2
- APBA1 | c.1439_1440insT p.V481Rfs*28 | Frame Shift Ins (INS) | VAF 57/196 reads (29%) | catalogued as COSV99595488; called by mutect2, pindel, varscan2
- APEX2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100237991; called by muse, mutect2, varscan2
- ARHGAP45 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100490429; called by muse, mutect2, varscan2
- ARHGEF12 | c.2143C>A p.P715T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV100754670; called by muse, mutect2, varscan2
- ASB9 | c.67A>T p.R23W | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100995378; called by muse, mutect2, varscan2
- ASCL1 | c.709T>A p.*237Rext*64 | Nonstop Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99901901; called by muse, mutect2, varscan2
- ATP2B3 | c.2985C>A p.N995K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99683130; called by muse, mutect2, varscan2
- ATP2C1 | c.361-2A>T p.X121_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as CS077347, COSV100146301; called by muse, mutect2, varscan2
- ATP6V0A2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100376830; called by muse, mutect2, varscan2
- ATP7A | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 123/611 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430281; called by muse, mutect2, varscan2
- AWAT1 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as COSV100997175; called by muse, mutect2, varscan2
- BACH1 | c.2071G>C p.G691R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99727943, COSV99728427; called by muse, mutect2, varscan2
- BDP1 | c.2495A>T p.E832V | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV62435824; called by muse, mutect2, varscan2
- BDP1 | c.2496G>T p.E832D | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as COSV100702747; called by muse, mutect2, varscan2
- BDP1 | c.5637C>G p.D1879E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100702748; called by muse, mutect2
- BEST2 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV50360669; called by muse, mutect2, varscan2
- BNIP5 | c.1803C>A p.Y601* | Nonsense Mutation (SNP) | VAF 52/192 reads (27%) | catalogued as COSV101465114; called by muse, varscan2
- BPTF | c.8878G>A p.D2960N | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV100074139; called by muse, mutect2, varscan2
- C10orf71 | c.284G>T p.W95L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60504174, COSV60508433; called by muse, mutect2, varscan2
- C6orf118 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100024127; called by muse, mutect2, varscan2
- C8A | c.1613C>A p.A538E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV63483590; called by muse, varscan2
- CACNA1S | c.2633T>G p.V878G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100754683; called by muse, mutect2, varscan2
- CACNA2D3 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99870584; called by muse, mutect2, varscan2
- CALN1 | c.522G>C p.E174D (on ENST00000329008 / NM_001017440.3; = p.E216D on NM_031468.4) | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100205010; called by muse, mutect2, varscan2
- CAMK2B | c.389T>A p.M130K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.209); catalogued as COSV99322775; called by muse, mutect2, varscan2
- CASP10 | c.1315G>T p.G439C (on ENST00000272879 / NM_032974.5; = p.G396C on NM_001230.5) | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628745; called by muse, mutect2, varscan2
- CATSPERE | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1307589732, COSV100834933; called by muse, mutect2
- CBLL2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100081475, COSV100081801; called by muse, mutect2, varscan2
- CCDC110 | c.1844A>G p.Q615R | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV100293683; called by muse, mutect2, varscan2
- CCL19 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs556438266, COSV100323118; called by muse, mutect2, varscan2
- CDKL5 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV101184045; called by muse, mutect2, varscan2
- CDKL5 | c.1912A>G p.R638G | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101184046; called by muse, mutect2, varscan2
- CDYL2 | c.932T>A p.L311Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101629511; called by muse, mutect2
- CEP85L | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100820995; called by muse, mutect2, varscan2
- CERS3 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs199763147, COSV52576684; called by muse, mutect2, varscan2
- CETN2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 24/231 reads (10%) | catalogued as COSV100938605; called by muse, mutect2, varscan2
- CFAP221 | c.2229C>A p.C743* | Nonsense Mutation (SNP) | VAF 30/172 reads (17%) | catalogued as COSV54653857, COSV99731948; called by muse, mutect2, varscan2
- CFAP47 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as rs781233621, COSV99934423; called by muse, mutect2, varscan2
- CHST6 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV100178265, COSV60001182; called by muse, mutect2, varscan2
- CLEC4M | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV50216865, COSV99940363; called by muse, mutect2, varscan2
- CLPSL1 | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100870175; called by muse, varscan2
- CLSTN2 | c.1738C>G p.R580G | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV71723325, COSV71725403; called by muse, mutect2, varscan2
- CNGA3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.122); catalogued as rs374938560, COSV55624287, COSV55627390; called by muse, mutect2, varscan2
- CNTNAP5 | c.2059C>A p.L687M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101443076; called by muse, mutect2
- COBL | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as rs757322624, COSV99471350; called by muse, mutect2
- COL11A2 | c.3386G>T p.G1129V (on ENST00000341947 / NM_080680.3; = p.G1022V on NM_080679.2) | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553478; called by muse, mutect2, varscan2
- COL12A1 | c.8840C>T p.P2947L | Missense Mutation (SNP) | VAF 77/425 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751239090, COSV59392201; called by muse, mutect2, varscan2
- COL13A1 | c.1427G>T p.G476V (on ENST00000398978 / NM_001130103.2; = p.G419V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637292; called by muse, mutect2, varscan2
- COL24A1 | c.3199C>G p.P1067A | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV100992915; called by muse, mutect2
- COL27A1 | c.4664A>G p.K1555R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV100620743; called by muse, mutect2, varscan2
- COMP | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99721315; called by muse, varscan2
- CORO1B | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100396249; called by muse, mutect2
- CORO2A | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100673978; called by muse, mutect2, varscan2
- CPLANE1 | c.8765A>T p.E2922V | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949704; called by muse, mutect2, varscan2
- CPSF6 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV99879015; called by muse, mutect2, varscan2
- CR2 | c.2617G>T p.G873* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV100889535, COSV100889550; called by muse, mutect2, varscan2
- CRHBP | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV57190637; called by muse, mutect2, varscan2
- CRIM1 | c.2962T>A p.S988T | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.073); catalogued as COSV99752480; called by muse, mutect2, varscan2
- CSMD1 | c.8455G>T p.E2819* (on ENST00000520002; = p.E2818* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100144229, COSV59369563; called by muse, mutect2
- CSMD3 | c.1639A>T p.T547S (on ENST00000297405 / NM_001363185.1; = p.T443S on NM_052900.3) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs1392847353, COSV99825585; called by muse, mutect2, varscan2
- CTNNA2 | c.2074C>A p.Q692K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV100559527, COSV58160643; called by muse, mutect2, varscan2
- CXorf21 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100973220; called by muse, mutect2, varscan2
- CYP2C8 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750902318, COSV100987882; called by muse, mutect2, varscan2
- DBN1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99445562; called by muse, mutect2, varscan2
- DCP1B | c.572A>C p.Y191S | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV99767244; called by muse, mutect2, varscan2
- DDX4 | c.2098-1G>T p.X700_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100737334; called by muse, mutect2, varscan2
- DDX4 | c.2098G>T p.G700C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100737337; called by muse, mutect2, varscan2
- DDX60L | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs749222089, COSV99486987; called by muse, mutect2
- DEUP1 | c.432G>A p.E144= | Splice Region (SNP) | VAF 25/118 reads (21%) | catalogued as COSV99976688; called by muse, mutect2, varscan2
- DGKB | c.1476A>T p.L492F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51768356; called by muse, mutect2, varscan2
- DHX37 | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.408); catalogued as COSV100438982; called by mutect2, varscan2
- DNAH9 | c.10129T>A p.C3377S | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV99304261; called by muse, mutect2, varscan2
- DOCK10 | c.4840G>A p.V1614M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99287725; called by muse, mutect2
- DOCK4 | c.3153G>T p.M1051I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV101447787; called by mutect2, varscan2
- DPF3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 57/258 reads (22%) | catalogued as rs533714896, COSV63498537; called by muse, mutect2, varscan2
- DPP6 | c.18G>C p.M6I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.38); catalogued as COSV101341254, COSV101341966; called by muse, mutect2, varscan2
- DSG4 | c.1635T>C p.N545= | Splice Region (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100355372; called by muse, mutect2, varscan2
- DYTN | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101123939; called by muse, mutect2, varscan2
- EFHC2 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV101375441; called by muse, mutect2, varscan2
- EGFLAM | c.2506G>A p.E836K (on ENST00000354891 / NM_001205301.2; = p.E828K on NM_152403.4) | Missense Mutation (SNP) | VAF 33/357 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV59299371; called by muse, mutect2
- EHD2 | c.590C>G p.S197W | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99621645; called by muse, mutect2
- ELAVL2 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV99805497; called by muse, mutect2, varscan2
- EMILIN2 | c.2302C>A p.H768N | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV99598144; called by muse, mutect2, varscan2
- ERICH3 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 119/517 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100443465, COSV58599791; called by muse, mutect2, varscan2
- EYS | c.341G>C p.C114S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100675702, COSV100676978; called by muse, mutect2, varscan2
- F8 | c.2933C>A p.S978* | Nonsense Mutation (SNP) | VAF 30/251 reads (12%) | catalogued as CM111351, COSV100811257; called by muse, mutect2, varscan2
- FAM114A1 | c.657A>C p.T219= | Splice Region (SNP) | VAF 22/109 reads (20%) | catalogued as COSV100729172; called by muse, mutect2, varscan2
- FAM114A1 | c.657+1G>A p.X219_splice | Splice Site (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100729176; called by muse, mutect2, varscan2
- FAM135B | c.1265A>C p.N422T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1407161622, COSV99419320; called by muse, mutect2, varscan2
- FAM13C | c.74A>T p.D25V | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.463); catalogued as COSV53253781; called by muse, mutect2, varscan2
- FAM47A | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV100649779; called by muse, mutect2
- FAM47C | c.467A>C p.E156A | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100792302; called by muse, varscan2
- FAM47C | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792303; called by muse, varscan2
- FAM71B | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 120/420 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100261823; called by muse, mutect2, varscan2
- FANCM | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV99950487; called by muse, mutect2, varscan2
- FCGR2C | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100912527; called by muse, mutect2
- FLNA | c.5091T>G p.D1697E (on ENST00000369850 / NM_001110556.2; = p.D1689E on NM_001456.3) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV100774296; called by muse, mutect2
- FLNA | c.3073G>C p.G1025R | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100774297; called by muse, mutect2
- FMR1 | c.1364C>A p.T455K | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.122); catalogued as COSV99502968; called by muse, mutect2, varscan2
- FMR1 | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.079); catalogued as rs1557181787, COSV54428027, COSV99502969; called by muse, mutect2, varscan2
- FNDC3B | c.3175+1G>T p.X1059_splice | Splice Site (SNP) | VAF 27/84 reads (32%) | catalogued as COSV100393636; called by muse, mutect2, varscan2
- FOLR1 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100398516; called by muse, mutect2, varscan2
- FRMPD3 | c.4238del p.G1413Afs*12 | Frame Shift Del (DEL) | VAF 17/167 reads (10%) | catalogued as COSV52189566; called by mutect2, pindel, varscan2
- FRS2 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100165752; called by muse, mutect2, varscan2
- FUT8 | c.1646G>T p.R549M (on ENST00000360689 / NM_001371534.1; = p.R386M on NM_004480.4) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV100651062; called by muse, mutect2, varscan2
- GABRD | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV101059509; called by muse, mutect2, varscan2
- GABRE | c.1358T>A p.F453Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.486); catalogued as COSV100944217; called by muse, mutect2, varscan2
- GABRG1 | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV54950653, COSV54950897; called by muse, mutect2, varscan2
- GABRG1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.309); catalogued as COSV99777450; called by muse, mutect2, varscan2
- GALK2 | c.786G>C p.W262C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV100508621; called by muse, mutect2, varscan2
- GALNT13 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV67229954; called by muse, mutect2, varscan2
- GDPD5 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.367); catalogued as rs752772755, COSV100409095; called by muse, mutect2, varscan2
- GEMIN8 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256928; called by muse, mutect2, varscan2
- GJA8 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53790896; called by muse, mutect2, varscan2
- GOLGB1 | c.8717A>G p.Q2906R | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.964); catalogued as COSV100510360; called by muse, mutect2
- GPER1 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV99866762; called by muse, mutect2, varscan2
- GPR148 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV99998509; called by muse, mutect2, varscan2
- GPR50 | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.308); catalogued as COSV99505688; called by muse, mutect2, varscan2
- GPRASP1 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100850913; called by muse, mutect2, varscan2
- GPRIN3 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100310601; called by muse, mutect2, varscan2
- GRIK3 | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV100901384; called by muse, mutect2, varscan2
- GRIK5 | c.1564A>T p.S522C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99490029; called by muse, mutect2, varscan2
- GRIN3A | c.1342T>A p.S448T | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100701370; called by muse, mutect2, varscan2
- GSPT2 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100467920, COSV61214028; called by muse, mutect2
- GTF2E1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99381747; called by muse, mutect2, varscan2
- GTPBP8 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99868217; called by muse, mutect2, varscan2
- H1-6 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs150306409; called by muse, varscan2
- H2AC17 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.151); catalogued as rs369136451; called by muse, mutect2, varscan2
- HAO1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66492507; called by muse, mutect2, varscan2
- HAO1 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113137; called by muse, mutect2
- HDAC6 | c.3541G>T p.A1181S | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs782778504, COSV100490584; called by muse, mutect2, varscan2
- HDX | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV99946656; called by muse, mutect2, varscan2
- HECW1 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs983774784, COSV101222614, COSV101222856; called by muse, mutect2, varscan2
- HELQ | c.861T>A p.S287R | Missense Mutation (SNP) | VAF 82/338 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99787429; called by muse, mutect2, varscan2
- HGF | c.531T>A p.C177* | Nonsense Mutation (SNP) | VAF 52/163 reads (32%) | catalogued as COSV99735695; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.742G>T p.G248* (on ENST00000354667 / NM_031243.3; = p.G236* on NM_002137.4) | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV100668213; called by muse, mutect2
- ICOS | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV100320277; called by muse, mutect2, varscan2
- IGFBP2 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99288298; called by muse, mutect2, varscan2
- IL1RL1 | c.610+1G>A p.X204_splice | Splice Site (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99293641; called by muse, mutect2
- IL1RL1 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99293645; called by muse, mutect2, varscan2
- IMPG1 | c.1618G>T p.V540F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100886069; called by muse, mutect2, varscan2
- IRS1 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100524036; called by muse, mutect2, varscan2
- ITCH | c.2152C>A p.H718N (on ENST00000262650 / NM_001257137.3; = p.H677N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99392026; called by muse, mutect2, varscan2
- ITGA6 | c.2854A>G p.R952G (on ENST00000442250; = p.R913G on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/405 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs770287742, COSV99905113; called by muse, mutect2, varscan2
- JPH3 | c.2224C>A p.L742M | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99412864; called by muse, mutect2, varscan2
- KALRN | c.1998G>C p.E666D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV99562286; called by muse, mutect2, varscan2
- KCNH4 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99236780; called by muse, mutect2, varscan2
- KCNH6 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.361); catalogued as COSV100120799; called by muse, mutect2, varscan2
- KCNIP4 | c.335A>C p.Y112S | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100749071; called by muse, mutect2, varscan2
- KCNK1 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV64035388; called by muse, mutect2, varscan2
- KCNMA1 | c.2586G>A p.M862I (on ENST00000286628 / NM_001161352.2; = p.M804I on NM_002247.4) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99695142; called by muse, mutect2, varscan2
- KCNU1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 37/274 reads (14%) | catalogued as COSV101298931; called by muse, mutect2, varscan2
- KCTD13 | c.245-2A>G p.X82_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as rs1259623258, COSV100442010; called by muse, mutect2, varscan2
- KERA | c.618T>A p.N206K | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99899317; called by muse, mutect2, varscan2
- KHDRBS2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV55425428, COSV99831192; called by muse, mutect2, varscan2
- KIAA1217 | c.5607T>G p.H1869Q | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV100286223; called by muse, mutect2, varscan2
- KIF17 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.081); catalogued as COSV99928557; called by muse, mutect2, varscan2
- KIT | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99853352; called by muse, mutect2, varscan2
- KLHL28 | c.1460A>C p.H487P | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100752985; called by muse, mutect2, varscan2
- KLHL6 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV100384327, COSV100385110; called by muse, mutect2, varscan2
- KRTAP1-5 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.096); catalogued as COSV100721356, COSV62624171; called by muse, mutect2, varscan2
- LDB3 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV53948432, COSV99554779; called by muse, mutect2, varscan2
- LHX8 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99633122; called by muse, mutect2, varscan2
- LIPK | c.771C>G p.N257K | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV101344950; called by muse, mutect2, varscan2
- LPCAT4 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148843; called by muse, mutect2, varscan2
- LRFN2 | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV100599125; called by muse, mutect2, varscan2
- LRP1B | c.12389G>T p.G4130V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101252970, COSV67229281; called by muse, mutect2, varscan2
- LRP5 | c.4349G>A p.G1450D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs1459295469, COSV99591462; called by muse, mutect2, varscan2
- LRRC18 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV99628505; called by muse, mutect2, varscan2
- LRRC4C | c.1694C>A p.T565N | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV99537053; called by muse, mutect2, varscan2
- MAGEA1 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100756610; called by muse, varscan2
- MAGEB10 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV100775150; called by muse, mutect2, varscan2
- MAGEC1 | c.2339G>T p.S780I | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV99594893; called by muse, mutect2, varscan2
- MAGEC3 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs552092345, COSV100024907; called by muse, mutect2, varscan2
- MAGI3 | c.1472G>C p.C491S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100288138; called by muse, mutect2
- MAP2K6 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV100765038; called by muse, mutect2, varscan2
- MCTS1 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100989133; called by muse, mutect2, varscan2
- MED12 | c.5138G>C p.R1713P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99048841; called by muse, mutect2
- MINDY4 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs1462875022, COSV54678221, COSV99518222, COSV99518349; called by muse, mutect2, varscan2
- MMP20 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99497447; called by muse, mutect2, varscan2
- MMS22L | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV99246148; called by muse, mutect2, varscan2
- MORC4 | c.2719C>A p.L907I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV99716835; called by muse, mutect2, varscan2
- MUC5AC | c.929C>A p.T310N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); catalogued as rs1427738592, COSV100650523; called by muse, mutect2, varscan2
- MXD3 | c.307A>G p.R103G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100293463; called by muse, mutect2, varscan2
- MYBPC1 | c.2704G>T p.E902* (on ENST00000550270 / NM_206820.2; = p.E909* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 31/399 reads (8%) | catalogued as COSV100637759; called by muse, mutect2
- MYCBP2 | c.3302+1G>T p.X1101_splice (on ENST00000357337; = p.X1139_splice on NM_015057.5) | Splice Site (SNP) | VAF 23/135 reads (17%) | catalogued as COSV100629278; called by muse, mutect2, varscan2
- MYL5 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1451332319, COSV100448346; called by muse, mutect2, varscan2
- MYO1H | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100183131, COSV60448338; called by muse, mutect2
- MYO1H | c.1009A>T p.R337* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100183133; called by muse, mutect2, varscan2
- NAA80 | c.694G>T p.A232S (on ENST00000417393 / NM_001200018.2; = p.A254S on NM_012191.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99807445; called by muse, mutect2
- NAV3 | c.1337T>A p.L446* | Nonsense Mutation (SNP) | VAF 43/192 reads (22%) | catalogued as COSV99887182; called by muse, mutect2, varscan2
- NAV3 | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57084970, COSV99886244; called by muse, mutect2, varscan2
- NAV3 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57090774, COSV99887188; called by muse, mutect2, varscan2
- NCBP2L | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966479; called by muse, mutect2, varscan2
- NECTIN4 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100919818; called by muse, mutect2
- NEXMIF | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 27/186 reads (15%) | catalogued as COSV50022151, COSV99279709; called by muse, mutect2, varscan2
- NF1 | c.6536G>T p.R2179L (on ENST00000358273 / NM_001042492.3; = p.R2158L on NM_000267.3) | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs772639479, COSV100646073; called by muse, mutect2, varscan2
- NGDN | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV101238832; called by muse, mutect2, varscan2
- NLGN1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV100848773; called by muse, mutect2, varscan2
- NLGN1 | c.1793A>G p.Y598C | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848774; called by muse, mutect2, varscan2
- NLRP14 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV100204589; called by muse, mutect2, varscan2
- NLRP3 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100275300; called by muse, mutect2, varscan2
- NLRP3 | c.2472G>T p.L824F | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760112424, COSV100275303; called by muse, mutect2
- NLRP4 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 31/217 reads (14%) | catalogued as COSV56712791; called by muse, mutect2, varscan2
- NLRP5 | c.2755A>G p.R919G | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101173392; called by muse, mutect2, varscan2
- NUP160 | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV101021312; called by muse, mutect2, varscan2
- OGDHL | c.2754G>T p.Q918H | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100934206, COSV65102466; called by muse, mutect2, varscan2
- OLR1 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376294; called by muse, mutect2, varscan2
- OPN1LW | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.864); catalogued as COSV100886853; called by muse, mutect2, varscan2
- OR10A3 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.745); catalogued as COSV100660222; called by muse, mutect2, varscan2
- OR10K1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99193230; called by muse, varscan2
- OR10K2 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as COSV59222412, COSV59222806; called by muse, mutect2, varscan2
- OR10S1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101602444; called by muse, mutect2, varscan2
- OR2L13 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63549550; called by muse, mutect2
- OR2T12 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.71); catalogued as COSV100527544; called by muse, mutect2, varscan2
- OR2T3 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100613091; called by muse, mutect2, varscan2
- OR4A47 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as rs1472091465, COSV101487051; called by muse, mutect2, varscan2
- OR4B1 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100535486; called by muse, mutect2, varscan2
- OR4C12 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100078282; called by muse, mutect2
- OR4K2 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100064102; called by muse, mutect2
- OR4N5 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61321553; called by muse, mutect2, varscan2
- OR4Q3 | c.362T>A p.M121K | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100056729; called by muse, mutect2, varscan2
- OR5B17 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs775710411, COSV100641854; called by muse, mutect2, varscan2
- OR5D16 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004098, COSV65721938; called by muse, mutect2, varscan2
- OR5L1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 105/486 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100449927; called by muse, mutect2, varscan2
- OR8A1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99420335; called by muse, mutect2, varscan2
- OR8H3 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 96/426 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100538753, COSV57910130; called by muse, mutect2, varscan2
- OR9G4 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100265007; called by muse, mutect2, varscan2
- OTOA | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99623635; called by muse, mutect2, varscan2
- PARVG | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100796028; called by muse, mutect2
- PCDH11X | c.32C>A p.A11E | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100008489, COSV53454550; called by muse, mutect2, varscan2
- PCDHA5 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100972118; called by muse, mutect2, varscan2
- PCDHB14 | c.67T>A p.L23M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.04); catalogued as COSV99505572; called by muse, mutect2, varscan2
- PCDHGA12 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52751495, COSV99338251; called by muse, mutect2, varscan2
- PCLO | c.12094G>T p.D4032Y | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61667325; called by muse, mutect2, varscan2
- PDE1C | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100371120; called by muse, mutect2, varscan2
- PDE3A | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100761693; called by muse, mutect2, varscan2
- PDE4DIP | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 211/390 reads (54%) | catalogued as COSV100516752; called by muse, mutect2, varscan2
- PDE8B | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99366187; called by muse, mutect2, varscan2
- PDE9A | c.1558G>T p.V520F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99371082; called by muse, mutect2, varscan2
- PDLIM5 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 25/131 reads (19%) | catalogued as COSV100523354, COSV58747786; called by muse, mutect2, varscan2
- PDYN | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV99452709; called by muse, mutect2, varscan2
- PEAK1 | c.3268G>T p.G1090* | Nonsense Mutation (SNP) | VAF 42/149 reads (28%) | catalogued as COSV100432468; called by muse, mutect2, varscan2
- PGAM4 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430279; called by muse, mutect2, varscan2
- PHC3 | c.751A>T p.T251S (on ENST00000494943 / NM_001308116.2; = p.T263S on NM_024947.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV101520141; called by muse, mutect2, varscan2
- PHKA2 | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV101176657; called by muse, mutect2, varscan2
- PHKA2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101176659; called by muse, mutect2, varscan2
- PHKB | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100065639; called by muse, mutect2, varscan2
- PIGO | c.2312C>G p.A771G | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV99956425; called by muse, mutect2
- PIGO | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1166737574, COSV99956428; called by muse, mutect2
- PIH1D1 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV99221012; called by muse, mutect2, varscan2
- PIK3C3 | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV100010362; called by muse, mutect2
- PIWIL1 | c.729T>G p.S243R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99806015; called by muse, mutect2, varscan2
- PLD5 | c.356G>T p.G119V (on ENST00000442594; = p.G57V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100138876; called by muse, mutect2, varscan2
- PLD5 | c.355G>C p.G119R (on ENST00000442594; = p.G57R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100138879; called by muse, mutect2, varscan2
- PLPP2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99514468; called by muse, mutect2, varscan2
- PLXNA3 | c.2831G>T p.R944L | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs1193337165, COSV100859818, COSV63753753; called by muse, mutect2, varscan2
- PLXNB3 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737137; called by muse, mutect2, varscan2
- PMS1 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100575464; called by muse, mutect2, varscan2
- POLA1 | c.153C>A p.V51= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100985039; called by muse, mutect2, varscan2
- POTEM | c.940T>A p.C314S | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.329); catalogued as rs1394704291; called by muse, mutect2, varscan2
- PPM1K | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99900851; called by muse, mutect2, varscan2
- PPP1R15B | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV100916299; called by muse, mutect2, varscan2
- PPP1R16B | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV55380372; called by muse, mutect2, varscan2
- PREX2 | c.4052A>T p.Y1351F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99905249; called by muse, mutect2, varscan2
- PRKD1 | c.1673-1G>T p.X558_splice | Splice Site (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100119328; called by muse, mutect2, varscan2
- PRLR | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99184214; called by muse, mutect2, varscan2
- PRPF3 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100254502; called by muse, mutect2
- PRR19 | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100003642; called by muse, mutect2, varscan2
- PRRC2B | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV61937124; called by muse, mutect2, varscan2
- PRSS35 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100864035; called by muse, mutect2, varscan2
- PTK6 | c.245G>C p.C82S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV99420310; called by muse, mutect2
- PTPRB | c.5214C>G p.P1738= | Splice Region (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99715962; called by muse, mutect2, varscan2
- PTPRD | c.5552C>A p.T1851N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100643468; called by muse, mutect2, varscan2
- PTPRD | c.5513G>A p.G1838E | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100643471; called by muse, mutect2, varscan2
- PTPRE | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV99616964; called by muse, mutect2, varscan2
- PTPRO | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99839778; called by muse, mutect2, varscan2
- RALGPS2 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.496); catalogued as COSV100243550; called by muse, mutect2, varscan2
- RASGEF1C | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs760031898, COSV63186161; called by muse, mutect2, varscan2
- RBM28 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99775497; called by muse, mutect2, varscan2
- RFX4 | c.1363C>A p.L455I (on ENST00000392842 / NM_213594.3; = p.L361I on NM_032491.6) | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99985398; called by muse, mutect2, varscan2
- RFX6 | c.2596C>G p.R866G | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as CM1512294, COSV100263268, COSV60584562; called by muse, mutect2, varscan2
- RHBG | c.690G>C p.W230C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99659173; called by muse, mutect2, varscan2
- RHEX | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 26/171 reads (15%) | catalogued as rs1306431885, COSV100520016; called by muse, mutect2, varscan2
- RTL9 | c.2197A>T p.M733L | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101511626; called by muse, mutect2, varscan2
- RTN2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs138317158; called by muse, mutect2, varscan2
- RYR2 | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100768163; called by muse, mutect2, varscan2
- SALL1 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99171577, COSV99192553; called by muse, mutect2, varscan2
- SATL1 | c.10C>A p.P4T (on ENST00000395409; = p.P191T on NM_001012980.2) | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV100260679; called by muse, mutect2
- SCN8A | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 29/169 reads (17%) | catalogued as rs1555214322, COSV61989293; called by muse, mutect2, varscan2
- SEC14L3 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs752658817, COSV53179955, COSV99306937; called by muse, mutect2, varscan2
- SELENOS | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.34); catalogued as COSV99574450; called by muse, mutect2, varscan2
- SETD5 | c.3337C>A p.H1113N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100200177; called by muse, mutect2, varscan2
- SHANK1 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99520277; called by muse, mutect2, varscan2
- SHROOM2 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101098180; called by muse, mutect2, varscan2
- SHROOM2 | c.3684C>A p.S1228R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as COSV101098183; called by muse, mutect2
- SI | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100014158; called by muse, mutect2, varscan2
- SIAE | c.1075T>G p.F359V | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99422177; called by muse, mutect2, varscan2
- SIX6 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.163); catalogued as rs1383480571, COSV100576440; called by muse, mutect2
- SLC16A9 | c.1436T>A p.L479Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101264314; called by muse, mutect2, varscan2
- SLC17A2 | c.1259C>T p.A420V (on ENST00000265425; = p.Q371* on NM_005835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99613921; called by muse, mutect2, varscan2
- SLC22A3 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780018864, COSV51718519; called by muse, mutect2, varscan2
- SLC22A3 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99278360; called by muse, mutect2, varscan2
- SLC25A39 | c.1060G>T p.D354Y (on ENST00000377095 / NM_001143780.3; = p.D346Y on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99835120; called by muse, mutect2, varscan2
- SLC39A6 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99309377; called by muse, mutect2, varscan2
- SLC4A3 | c.2348G>T p.R783L | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV99812439; called by muse, mutect2
- SLC6A14 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.936); catalogued as COSV100903067, COSV100903147; called by muse, mutect2, varscan2
- SLC7A3 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99979339; called by muse, mutect2, varscan2
- SLC9A4 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99762729; called by muse, mutect2, varscan2
- SLCO1A2 | c.1399G>C p.A467P | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100261356; called by muse, mutect2, varscan2
- SLCO1C1 | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1262628085, COSV99858502; called by muse, mutect2, varscan2
- SLCO1C1 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299681114, COSV99858509; called by muse, mutect2, varscan2
- SLF2 | c.1808G>T p.S603I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99488515; called by muse, mutect2, varscan2
- SLIT2 | c.3871G>T p.A1291S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.057); catalogued as rs765899590, COSV99881147; called by muse, mutect2, varscan2
- SLITRK4 | c.565A>T p.R189* | Nonsense Mutation (SNP) | VAF 49/212 reads (23%) | catalogued as COSV100567167; called by muse, mutect2, varscan2
- SLITRK5 | c.929C>A p.P310Q | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100280334, COSV61522304; called by muse, mutect2, varscan2
- SMARCA4 | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99065505; called by muse, mutect2, varscan2
- SNX30 | c.1224G>T p.M408I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100953751; called by muse, mutect2, varscan2
- SPO11 | c.634+1G>T p.X212_splice | Splice Site (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100625631; called by muse, mutect2
- SPTB | c.3502C>A p.L1168I | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.273); catalogued as rs145875201; called by muse, mutect2, varscan2
- SQOR | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99525525; called by muse, varscan2
- SRD5A3 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99947987; called by muse, mutect2, varscan2
- SRGAP1 | c.2659C>A p.P887T | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV100754282; called by muse, mutect2, varscan2
- SRGAP3 | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100840730; called by muse, mutect2, varscan2
- ST8SIA1 | c.254G>C p.C85S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99682770; called by muse, mutect2, varscan2
- ST8SIA2 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 19/165 reads (12%) | PolyPhen benign (0); catalogued as COSV99184370; called by muse, mutect2, varscan2
- STARD4 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99685226; called by muse, mutect2, varscan2
- STON1 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 70/278 reads (25%) | catalogued as COSV100561495; called by muse, mutect2, varscan2
- SUGCT | c.560A>T p.H187L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100000073, COSV59348335; called by muse, mutect2, varscan2
- SYT12 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375154870; called by muse, mutect2, varscan2
- SYT3 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100143885; called by muse, mutect2, varscan2
- SZT2 | c.2069G>T p.R690L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100986895; called by muse, varscan2
- TAOK1 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 54/232 reads (23%) | catalogued as COSV99913550; called by muse, mutect2, varscan2
- TAS1R3 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100229275; called by muse, mutect2, varscan2
- TBC1D9B | c.3421C>G p.Q1141E (on ENST00000356834 / NM_198868.3; = p.Q1124E on NM_015043.4) | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.038); catalogued as COSV99481312; called by muse, mutect2, varscan2
- TCEAL6 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101035909, COSV65653934; called by muse, mutect2, varscan2
- TCN1 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV99953098; called by muse, mutect2, varscan2
- TECTA | c.3781T>A p.S1261T | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99878691; called by muse, varscan2
- TENM1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.294); catalogued as COSV100949130; called by muse, mutect2, varscan2
- TEX44 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100009598; called by muse, mutect2, varscan2
- TFDP3 | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100033205; called by muse, mutect2
- THOC2 | c.3868C>A p.P1290T | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs772379634, COSV55542725, COSV55554704; called by muse, mutect2, varscan2
- TICRR | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV99176033; called by muse, mutect2, varscan2
- TLL2 | c.1064T>G p.L355R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100780135; called by muse, mutect2, varscan2
- TM9SF2 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100816398; called by muse, mutect2, varscan2
- TMCO5A | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100148442; called by muse, mutect2, varscan2
- TMEM117 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861886; called by muse, mutect2, varscan2
- TMEM131 | c.5614G>T p.D1872Y | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1262976582, COSV99486639; called by muse, mutect2, varscan2
- TNR | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as COSV99687740; called by muse, mutect2, varscan2
- TOGARAM1 | c.2501T>C p.I834T | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100817831; called by muse, mutect2, varscan2
- TPH1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100000650; called by muse, mutect2, varscan2
- TRIM17 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99488087; called by muse, mutect2, varscan2
- TRIM42 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99647997; called by muse, mutect2, varscan2
- TRIM42 | c.1866C>A p.Y622* | Nonsense Mutation (SNP) | VAF 35/154 reads (23%) | catalogued as COSV99648001; called by muse, mutect2, varscan2
- TRIM56 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781156766, COSV100046983; called by muse, mutect2, varscan2
- TRIM58 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as rs1349504673, COSV63569515, COSV63571737; called by muse, mutect2, varscan2
- TRIP12 | c.5603G>T p.G1868V | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389426; called by muse, mutect2
- TRPC5 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53287122; called by muse, mutect2, varscan2
- TSC22D1 | c.266C>G p.S89W | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV101488067; called by muse, mutect2, varscan2
- TSPEAR | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100390176; called by muse, mutect2, varscan2
- TSPYL2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV100966262; called by muse, mutect2
- TTC14 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV99931825; called by muse, mutect2, varscan2
- TTN | c.39650C>G p.P13217R (on ENST00000591111; = p.P5793R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | PolyPhen probably damaging (0.999); catalogued as COSV100595545; called by muse, mutect2
- TTN | c.36556G>T p.V12186L (on ENST00000591111; = p.V4762L on NM_003319.4) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | PolyPhen benign (0.053); catalogued as COSV100595548; called by muse, mutect2, varscan2
- TTN | c.6535G>T p.E2179* (on ENST00000591111; = p.E2133* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 23/138 reads (17%) | catalogued as COSV100595553, COSV60177877; called by muse, mutect2, varscan2
- TUBB4A | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99899875; called by muse, mutect2, varscan2
- UNC79 | c.4325C>A p.A1442D (on ENST00000393151 / NM_001346218.2; = p.A1265D on NM_020818.5) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99825976; called by muse, mutect2, varscan2
- UPK1A | c.84G>C p.L28= | Splice Region (SNP) | VAF 45/157 reads (29%) | catalogued as COSV99721770; called by muse, mutect2, varscan2
- USP10 | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 37/184 reads (20%) | catalogued as COSV54749705; called by muse, mutect2
- USP11 | c.1312G>T p.V438L (on ENST00000218348; = p.V395L on NM_001371072.1) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99510702; called by muse, mutect2
- UTP25 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200728349, COSV71965910; called by muse, mutect2
- XIRP2 | c.1325C>G p.T442S (on ENST00000628543; = p.T617S on NM_152381.6) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs776944687, COSV54685810, COSV99738796; called by muse, mutect2, varscan2
- XKR7 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1287211370, COSV101629234; called by muse, mutect2, varscan2
- XRCC1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99486258; called by muse, mutect2
- ZBED1 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV100585232; called by muse, mutect2, varscan2
- ZCCHC7 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100382797; called by muse, mutect2, varscan2
- ZNF292 | c.7726G>T p.E2576* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100369808; called by muse, mutect2, varscan2
- ZNF326 | c.1607A>T p.Q536L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100437906; called by muse, mutect2, varscan2
- ZNF416 | c.210G>C p.W70C | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99543692; called by muse, mutect2
- ZNF449 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100202819; called by muse, mutect2, varscan2
- ZNF479 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | catalogued as rs1192313145, COSV58643700; called by muse, varscan2
- ZNF584 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV59723191; called by muse, mutect2, varscan2
- ZNF711 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99340667; called by muse, mutect2, varscan2
- ZNF777 | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99925003; called by muse, varscan2
- ZNF787 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99555350; called by muse, mutect2, varscan2
- ZNF836 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV100440624; called by muse, mutect2, varscan2
- ACACA | c.2891G>T p.S964I | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AFF2 | c.1414delinsAA p.P472Nfs*24 | Frame Shift Ins (INS) | VAF 38/232 reads (16%) | called by pindel, varscan2*
- ARAP2 | c.1076del p.G359Efs*29 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by pindel, varscan2
- CCK | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CUBN | c.4734del p.R1579Gfs*21 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel
- DNAH9 | c.7085_7093dup p.D2364_C2365insSAD | In Frame Ins (INS) | VAF 31/130 reads (24%) | called by mutect2, varscan2
- FOXD4L4 | c.1059del p.T354Pfs*73 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, varscan2
- FRG2C | c.322del p.Q108Kfs*14 | Frame Shift Del (DEL) | VAF 20/147 reads (14%) | called by mutect2, pindel, varscan2
- GNPTG | c.318_330del p.X106_splice | Splice Site (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- IGHV3-21 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.361); called by muse, mutect2
- MRC1 | c.4301C>A p.S1434* | Nonsense Mutation (SNP) | VAF 87/599 reads (15%) | called by muse, mutect2, varscan2
- MYO19 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR2C3 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR4C11 | c.24_45del p.E9Hfs*5 | Frame Shift Del (DEL) | VAF 17/189 reads (9%) | called by mutect2, pindel
- OR8B8 | c.439_440delinsA p.G147Mfs*17 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by pindel, varscan2*
- PRRC2A | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SPRY3 | c.843del p.K282Rfs*37 | Frame Shift Del (DEL) | VAF 16/148 reads (11%) | called by mutect2, pindel, varscan2
- SRRM3 | c.433del p.A145Pfs*62 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- TPTE | c.706G>C p.D236H (on ENST00000618007 / NM_199261.4; = p.D218H on NM_199259.4) | Missense Mutation (SNP) | VAF 41/1074 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV26-2 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRBC2 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.5724T>C p.H1908= | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as rs770187952, COSV101329933; called by muse, mutect2
- AC008397.2 | c.1746C>T p.I582= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV99441230; called by muse, mutect2, varscan2
- AMER1 | c.528C>A p.I176= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100365365; called by muse, mutect2, varscan2
- AP4B1 | c.636A>G p.Q212= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs746978125, COSV99870570; called by muse, mutect2
- ATP10A | c.4443A>G p.G1481= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV100790899; called by muse, mutect2, varscan2
- ATP23 | c.457C>A p.R153= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs867626853, COSV100274414; called by muse, mutect2, varscan2
- BBOX1 | c.825T>C p.H275= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99589445; called by muse, mutect2, varscan2
- BMS1 | c.93A>T p.L31= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV100996484; called by muse, mutect2, varscan2
- BPIFB6 | c.675G>A p.V225= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs760488590, COSV100848486; called by muse, mutect2, varscan2
- BRWD3 | c.3447G>T p.R1149= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV100955668; called by muse, mutect2, varscan2
- C7 | c.1308G>C p.V436= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100495432, COSV57470929, COSV57479187; called by muse, mutect2, varscan2
- C8A | c.1614A>G p.A538= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100776443; called by muse, mutect2, varscan2
- CCDC18 | c.3819G>A p.L1273= (on ENST00000343253 / NM_001306076.1; = p.L1274= on NM_206886.4) | Silent (SNP) | VAF 40/211 reads (19%) | catalogued as COSV100159241; called by muse, mutect2, varscan2
- CCT8L2 | c.573C>A p.I191= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100742569; called by muse, mutect2, varscan2
- CD5 | c.1449C>T p.S483= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs779186136, COSV57109272; called by muse, mutect2, varscan2
- CDH11 | c.843C>A p.A281= | Silent (SNP) | VAF 64/227 reads (28%) | catalogued as COSV51768799, COSV99217306; called by muse, mutect2, varscan2
- CDH9 | c.408G>T p.G136= | Silent (SNP) | VAF 94/432 reads (22%) | catalogued as COSV99141855; called by muse, mutect2, varscan2
- CFHR4 | c.1308C>A p.S436= (on ENST00000367416 / NM_001201551.2; = p.S190= on NM_006684.5) | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV52231709, COSV99259590; called by muse, mutect2, varscan2
- CLTCL1 | c.3336C>G p.A1112= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99594551; called by muse, mutect2, varscan2
- CSMD1 | c.7824G>T p.T2608= (on ENST00000520002; = p.T2607= on NM_033225.6) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs746936196, COSV100144233, COSV100151547; called by muse, mutect2, varscan2
- CSMD1 | c.2640T>A p.P880= (on ENST00000520002; = p.P879= on NM_033225.6) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100144234; called by muse, mutect2
- DEPDC5 | c.2556T>C p.S852= (on ENST00000400246; = p.S921= on NM_014662.5) | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99834443; called by muse, mutect2, varscan2
- DNAH11 | c.3459A>G p.T1153= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV100177355; called by muse, mutect2, varscan2
- EIF2AK2 | c.879C>T p.Y293= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs757581996, COSV99240328; called by muse, mutect2, varscan2
- ELAVL2 | c.849G>C p.L283= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV99805499; called by muse, mutect2, varscan2
- EPHA7 | c.2796A>G p.L932= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as COSV100993290; called by muse, mutect2, varscan2
- FAM110B | c.1014G>C p.V338= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100826020; called by muse, mutect2, varscan2
- FAM135B | c.837T>G p.V279= | Silent (SNP) | VAF 47/211 reads (22%) | catalogued as COSV99419324; called by muse, mutect2, varscan2
- FAM50A | c.369C>A p.T123= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99340858; called by muse, mutect2
- FAT4 | c.7548C>T p.H2516= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100627303; called by muse, mutect2, varscan2
- FBXL4 | c.1554G>A p.L518= | Silent (SNP) | VAF 39/176 reads (22%) | catalogued as COSV100013829, COSV100013879; called by muse, mutect2, varscan2
- FCHSD1 | c.1660C>T p.L554= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99781174; called by muse, mutect2, varscan2
- FER | c.333G>A p.K111= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV99811697; called by muse, mutect2, varscan2
- FKBP6 | c.375C>T p.P125= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as COSV99333721; called by muse, mutect2, varscan2
- GBA | c.837G>T p.L279= | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as rs371576958, COSV59171311; called by muse, mutect2, varscan2
- GBP5 | c.252T>A p.P84= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV100599983; called by muse, mutect2, varscan2
- GCN1 | c.5229C>T p.A1743= | Silent (SNP) | VAF 73/321 reads (23%) | catalogued as COSV100324690; called by muse, mutect2, varscan2
- HUWE1 | c.9219C>A p.V3073= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as COSV99470738; called by muse, mutect2
- IGLV3-32 | c.117C>A p.T39= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- IL10RA | c.1191C>A p.G397= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV99922881; called by muse, mutect2, varscan2
- INHBB | c.1056G>T p.T352= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV54677640, COSV99735644; called by muse, mutect2, varscan2
- INTS6L | c.2313T>A p.P771= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV100878019; called by muse, mutect2, varscan2
- IREB2 | c.2223T>C p.H741= | Silent (SNP) | VAF 103/354 reads (29%) | catalogued as rs1041096900, COSV51920773; called by muse, mutect2, varscan2
- KANK4 | c.345C>T p.A115= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV100587046; called by muse, mutect2, varscan2
- KCNH6 | c.771C>A p.A257= | Silent (SNP) | VAF 55/185 reads (30%) | catalogued as COSV100120802; called by muse, mutect2, varscan2
- KIF7 | c.1908C>G p.T636= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs199955444, COSV101067276; called by muse, mutect2, varscan2
- KIT | c.333T>C p.V111= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV99853351; called by muse, mutect2, varscan2
- KRT2 | c.465C>T p.V155= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as COSV59013349; called by muse, mutect2, varscan2
- KRT25 | c.630G>T p.L210= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as COSV100379813; called by muse, varscan2
- KY | c.1134G>A p.T378= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV101414943; called by muse, mutect2
- LIPG | c.708G>T p.V236= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99724278; called by muse, mutect2, varscan2
- LPAR4 | c.678G>T p.V226= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV101425077; called by muse, mutect2, varscan2
- MCF2 | c.1692G>T p.L564= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100644317; called by muse, varscan2
- MSLN | c.622C>T p.L208= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99557937; called by muse, mutect2, varscan2
- MUC16 | c.17355G>A p.R5785= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV101198276; called by muse, mutect2, varscan2
- MUC4 | c.2505C>T p.S835= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs752724482, COSV100639592; called by muse, mutect2, varscan2
- MYO1A | c.2955G>T p.R985= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100270604; called by muse, mutect2, varscan2
- MYO3A | c.2709G>T p.L903= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV99778475; called by muse, mutect2
- MYOC | c.315C>T p.D105= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV99231314; called by muse, mutect2, varscan2
- NCAPH | c.126G>T p.A42= | Silent (SNP) | VAF 45/178 reads (25%) | catalogued as rs139287054, COSV99545546; called by muse, mutect2, varscan2
- NCKAP1L | c.78C>T p.L26= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV53209039; called by muse, mutect2, varscan2
- NLRP13 | c.1461C>A p.A487= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100738048; called by muse, mutect2, varscan2
- OR1C1 | c.387C>A p.P129= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV101376185, COSV68715511; called by muse, mutect2, varscan2
- OR2G6 | c.837C>T p.T279= | Silent (SNP) | VAF 29/194 reads (15%) | catalogued as COSV100598035; called by muse, mutect2, varscan2
- OR5M8 | c.873T>A p.L291= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV100510552; called by muse, mutect2, varscan2
- OR6K3 | c.279C>A p.T93= (on ENST00000368146; = p.T77= on NM_001005327.2) | Silent (SNP) | VAF 160/429 reads (37%) | catalogued as COSV100933833; called by muse, mutect2, varscan2
- OR6S1 | c.483C>A p.P161= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100289279; called by muse, mutect2, varscan2
- OR8B8 | c.420G>C p.V140= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100044836; called by muse, varscan2
- OSBPL3 | c.1668G>A p.L556= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV100513718; called by muse, mutect2
- OTX1 | c.456A>T p.A152= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99246164; called by muse, mutect2, varscan2
- PARP8 | c.741C>T p.I247= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99890058; called by muse, mutect2, varscan2
- PM20D2 | c.1026T>C p.D342= | Silent (SNP) | VAF 30/222 reads (14%) | catalogued as COSV99248206; called by muse, mutect2, varscan2
- PSME1 | c.628C>A p.R210= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV99246023; called by muse, mutect2, varscan2
- PTPRU | c.183G>T p.R61= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV100111737; called by muse, mutect2, varscan2
- PYGL | c.2223G>A p.L741= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as COSV99368270; called by muse, mutect2, varscan2
- RAG1 | c.2766C>A p.L922= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100200671; called by muse, mutect2, varscan2
- RFPL4B | c.480G>T p.L160= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV101480661; called by muse, mutect2, varscan2
- RHPN1 | c.199A>C p.R67= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100000469; called by muse, varscan2
- RPS6KA6 | c.1041C>T p.F347= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV53123670, COSV99424137; called by muse, mutect2, varscan2
- SACS | c.10107C>A p.V3369= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV101207185, COSV101207668; called by muse, mutect2, varscan2
- SASH3 | c.393T>A p.S131= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV100795158; called by muse, mutect2, varscan2
- SAXO1 | c.102C>A p.L34= | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as COSV101000105, COSV65871050; called by muse, mutect2
- SERPINA3 | c.153C>G p.S51= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV101261613, COSV67587407; called by muse, mutect2, varscan2
- SI | c.2280T>A p.A760= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100014156; called by muse, mutect2, varscan2
- SMYD1 | c.162C>A p.T54= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV101352398; called by muse, mutect2, varscan2
- SYN3 | c.489G>T p.L163= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100248395; called by muse, mutect2, varscan2
- SYP | c.267G>T p.G89= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV99602728; called by muse, mutect2
- TBC1D15 | c.108A>T p.G36= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as COSV100041396; called by muse, mutect2, varscan2
- TECRL | c.627A>G p.A209= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as COSV101168486; called by muse, mutect2, varscan2
- THSD7A | c.3849C>T p.C1283= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV101439722; called by muse, mutect2, varscan2
- THSD7A | c.306C>G p.A102= | Silent (SNP) | VAF 60/159 reads (38%) | catalogued as COSV101448551, COSV101448836, COSV70261039; called by muse, mutect2, varscan2
- TMED2 | c.150G>T p.A50= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV51629776, COSV99147721; called by muse, mutect2, varscan2
- TOX2 | c.1317C>A p.I439= (on ENST00000358131 / NM_001098798.2; = p.I415= on NM_032883.3) | Silent (SNP) | VAF 48/219 reads (22%) | catalogued as COSV100363375; called by muse, mutect2, varscan2
- TRIM7 | c.453G>A p.V151= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99220013; called by muse, mutect2
- TTN | c.44514C>A p.G14838= (on ENST00000591111; = p.G7414= on NM_003319.4) | Silent (SNP) | VAF 68/296 reads (23%) | catalogued as COSV100595543; called by muse, mutect2, varscan2
- TXNDC16 | c.1954C>T p.L652= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV99908849; called by muse, mutect2, varscan2
- UPF2 | c.1635G>A p.K545= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100706950, COSV100707038, COSV62660784; called by muse, mutect2, varscan2
- UTP14A | c.55C>T p.L19= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV100930396; called by muse, mutect2
- VPS11 | c.750G>T p.R250= (on ENST00000620429; = p.R794= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100333537; called by muse, mutect2
- WRAP53 | c.834G>A p.T278= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs372166304; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- XPNPEP2 | c.807A>G p.T269= | Silent (SNP) | VAF 97/423 reads (23%) | catalogued as COSV100941154; called by muse, mutect2, varscan2
- ZEB1 | c.1752T>C p.P584= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as COSV100313675; called by muse, mutect2, varscan2
- ZNF598 | c.570G>A p.K190= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV101461928; called by muse, varscan2
- ZNF644 | c.2133T>C p.I711= | Silent (SNP) | VAF 53/246 reads (22%) | catalogued as COSV100494274; called by muse, mutect2, varscan2
- ZNF676 | c.249A>G p.Q83= (on ENST00000650058; = p.Q51= on NM_001001411.3) | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV101236102; called by muse, mutect2, varscan2
- ANKRD13D | c.*463A>T | 3'UTR (SNP) | VAF 25/139 reads (18%) | catalogued as COSV100398283; called by muse, mutect2, varscan2
- CD300LD | chr17:74592750 C>T | 5'Flank (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- ERBB4 | c.82+112101G>T | Intron (SNP) | VAF 20/94 reads (21%) | catalogued as rs1307091997, COSV99616962; called by muse, mutect2, varscan2
- IL36B | c.261+955C>A | Intron (SNP) | VAF 16/150 reads (11%) | catalogued as rs781159319, COSV99382488; called by muse, varscan2
- MFRP | chr11:119346291 G>T | 5'Flank (SNP) | VAF 9/49 reads (18%) | catalogued as COSV64128049; called by muse, mutect2
- MIR377 | n.34A>G | RNA (SNP) | VAF 29/216 reads (13%) | called by muse, mutect2, varscan2
- OR2W5 | n.644G>C | RNA (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- SNORD116-14 | n.53G>T | RNA (SNP) | VAF 53/301 reads (18%) | called by muse, mutect2, varscan2
- STMN2 | c.-2C>A | 5'UTR (SNP) | VAF 25/56 reads (45%) | catalogued as COSV99626134; called by muse, mutect2, varscan2
- TMEM99 | n.890A>G | RNA (SNP) | VAF 50/208 reads (24%) | catalogued as rs1231061372, COSV100053971; called by muse, mutect2, varscan2
- USH1C | c.1285-7489C>A | Intron (SNP) | VAF 31/161 reads (19%) | catalogued as COSV99139355; called by muse, mutect2, varscan2
- YOD1 | chr1:207052208 C>G | 5'Flank (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100262866; called by muse, mutect2, varscan2
